Somatic mutation profile of tumor specimen TCGA-AC-A62V-01A (aliquot TCGA-AC-A62V-01A-11D-A31U-09) from TCGA case TCGA-AC-A62V, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.6 years (21,389 days).
Specimen TCGA-AC-A62V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f02cebd5-5840-4c63-bdf2-af7677e112e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A62V-10A (Blood Derived Normal), aliquot TCGA-AC-A62V-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50df3075-8770-4971-9673-91d87dd82331

The open-access MAF lists 77 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 17, Frame Shift Del 3, Nonsense Mutation 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV100252811; called by muse, mutect2, varscan2
- ADCY7 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV54268372; called by muse, mutect2, varscan2
- AQP12A | c.313G>C p.A105P | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100538825; called by muse, mutect2, varscan2
- BCL11B | c.2495C>T p.A832V (on ENST00000357195 / NM_001282237.2; = p.A761V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100595611; called by muse, mutect2
- BTN1A1 | c.1442G>C p.R481T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99764433; called by muse, mutect2, varscan2
- C7orf31 | c.1636A>C p.N546H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as COSV99384006; called by muse, mutect2, varscan2
- CDC25B | c.275G>A p.R92Q (on ENST00000245960 / NM_021873.3; = p.R78Q on NM_004358.4) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV99847969; called by muse, mutect2, varscan2
- CEP112 | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 9/115 reads (8%) | catalogued as COSV101210800; called by muse, mutect2
- CHP2 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV100270185; called by mutect2, varscan2
- CYP2A13 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV57840266; called by muse, mutect2, varscan2
- DNAH3 | c.8504G>A p.G2835E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54563502; called by muse, mutect2, varscan2
- EDEM2 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993786; called by muse, mutect2
- ENPP7 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs530922212, COSV60386680; called by muse, mutect2, varscan2
- FBXO47 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100960751; called by muse, mutect2, varscan2
- FMN2 | c.4742G>T p.R1581I | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100145614, COSV60427184; called by muse, mutect2, varscan2
- GEMIN8 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as COSV100257046; called by muse, mutect2, varscan2
- GPX7 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100790890; called by muse, mutect2, varscan2
- GUCY2C | c.2336T>C p.V779A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99663753; called by muse, mutect2, varscan2
- HELZ | c.1619C>G p.P540R | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV100698813; called by muse, mutect2
- HNRNPK | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as COSV100699034; called by muse, mutect2, varscan2
- HOXA7 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99636523; called by muse, mutect2, varscan2
- IFT122 | c.2700G>T p.Q900H (on ENST00000348417 / NM_052989.3; = p.Q841H on NM_018262.4) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV99959441; called by muse, mutect2, varscan2
- INHBE | c.839G>A p.C280Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747468719, COSV99875308; called by muse, mutect2, varscan2
- ITGA9 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53247230, COSV99293030; called by muse, mutect2, varscan2
- KANK1 | c.3806C>T p.T1269M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775231755, COSV101206921; called by muse, mutect2, varscan2
- KRTAP12-3 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs782406301, COSV59951981; called by muse, mutect2, varscan2
- MAD1L1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV99766432; called by muse, mutect2, varscan2
- MGAT5 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs755158785, COSV56098797; called by muse, mutect2, varscan2
- MRPL32 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); catalogued as rs201769152; called by muse, mutect2, varscan2
- MYH7B | c.2430G>C p.K810N | Missense Mutation (SNP) | VAF 42/1166 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99482898; called by muse, mutect2
- NHLH1 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1431620541, COSV57483728; called by muse, mutect2, varscan2
- NOXO1 | c.195A>T p.R65S (on ENST00000397280 / NM_172168.3; = p.R64S on NM_144603.4) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as COSV99937055; called by muse, mutect2, varscan2
- NPTX1 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.943); catalogued as rs1466750124, COSV60775223, COSV60776878; called by muse, mutect2, varscan2
- OR4C11 | c.392C>A p.P131Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as COSV100155359; called by muse, mutect2, varscan2
- PCNX1 | c.3136T>A p.Y1046N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99455970; called by muse, mutect2, varscan2
- PPP3R2 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.03); catalogued as rs151037849; called by muse, mutect2, varscan2
- PRKAG2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99835450; called by muse, mutect2, varscan2
- RASA3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61866022; called by muse, mutect2, varscan2
- RIPPLY2 | c.255A>T p.K85N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100859507; called by muse, mutect2, varscan2
- RTP3 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs752009052, COSV56123773; called by mutect2, varscan2
- SEC62 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100427988, COSV61261080; called by muse, mutect2, varscan2
- SEMA4C | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100561045; called by muse, mutect2, varscan2
- SLC9A3R1 | c.592C>G p.R198G | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52852579, COSV99380096; called by muse, mutect2, varscan2
- SLC9C1 | c.2767G>C p.G923R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.454); catalogued as COSV99998131; called by muse, mutect2
- STRADB | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs865949332, COSV99524577; called by muse, mutect2, varscan2
- TMEM132D | c.969G>A p.R323= | Splice Region (SNP) | VAF 8/26 reads (31%) | catalogued as rs765924223, COSV101398227; called by muse, mutect2, varscan2
- TNRC6C | c.4131C>G p.I1377M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as COSV100050101, COSV56948239; called by muse, mutect2, varscan2
- TNRC6C | c.4168C>G p.H1390D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV100050104; called by muse, mutect2, varscan2
- TNS3 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs575738038, COSV60788562; called by muse, varscan2
- TUT7 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.703); catalogued as COSV99463173; called by muse, mutect2, varscan2
- UBE3A | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99217399; called by muse, mutect2, varscan2
- VWA8 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.792); catalogued as rs186939342, COSV55697962; called by muse, mutect2, varscan2
- ZNF71 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs372609144; called by muse, mutect2, varscan2
- ZP1 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760936498, COSV53923301, COSV53925679; called by muse, mutect2, varscan2
- ZSCAN10 | c.979G>A p.G327R (on ENST00000252463; = p.G382R on NM_032805.3) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs757518183; called by muse, mutect2, varscan2
- DCAF1 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- DNAJC2 | c.1554_1570del p.N518Kfs*22 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- GATA3 | c.986_990del p.R329Kfs*21 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | called by mutect2, pindel, varscan2
- ZSWIM3 | c.275_278del p.F92Sfs*4 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- ANGPTL5 | c.1092C>A p.T364= | Silent (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.915G>A p.A305= | Silent (SNP) | VAF 24/412 reads (6%) | catalogued as rs746454949, COSV100904314; called by muse, mutect2
- BEST1 | c.754C>T p.L252= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100077215; called by muse, mutect2, varscan2
- FAM221A | c.171C>T p.S57= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV100794342; called by muse, mutect2, varscan2
- HSP90B1 | c.1476C>A p.I492= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100236579; called by muse, mutect2, varscan2
- IGHA1 | c.648C>T p.T216= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs758877841; called by muse, mutect2
- KTN1 | c.3822T>C p.N1274= (on ENST00000395314 / NM_001271014.2; = p.N1217= on NM_004986.4) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100618334; called by muse, mutect2, varscan2
- MCTP2 | c.1461C>T p.S487= | Silent (SNP) | VAF 49/84 reads (58%) | catalogued as rs753961829, COSV100537527; called by muse, mutect2, varscan2
- NTNG2 | c.786C>T p.G262= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1336536224, COSV62365153, COSV62367421; called by muse, mutect2, varscan2
- NYAP2 | c.1134G>A p.A378= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs181896828, COSV56006195; called by muse, mutect2, varscan2
- PKD1L1 | c.5994G>A p.L1998= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99220117; called by muse, mutect2
- PLXNB2 | c.4464C>T p.S1488= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100834108, COSV100834221; called by muse, mutect2, varscan2
- RAPGEF1 | c.2364C>T p.R788= | Silent (SNP) | VAF 31/42 reads (74%) | catalogued as rs1350293317, COSV100940634; called by muse, mutect2, varscan2
- RYR2 | c.12018T>C p.S4006= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100771008; called by muse, mutect2, varscan2
- SNX33 | c.1533C>T p.D511= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs151175095; called by muse, mutect2
- TAAR6 | c.777C>A p.T259= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99256765; called by muse, mutect2, varscan2
- TECPR2 | c.2737C>T p.L913= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100850053; called by muse, mutect2, varscan2
- UBTFL2 | n.39G>C | RNA (SNP) | VAF 46/155 reads (30%) | called by muse, varscan2
